Gene-level copy-number profile of specimen HCM-SANG-0272-C20-85A from HCMI case HCM-SANG-0272-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0272-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d843b6b8-450f-4f22-8ddc-c01be47edc2d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0272-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/e9e83f26-64a2-43ae-ab0b-a3369aa967ab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 216; copy number 2: 10,838; copy number 3: 27,931; copy number 4: 12,685; copy number 5: 1,860; copy number 6: 1,793; copy number 7: 2,461; copy number 8: 154; copy number 9: 328; copy number 10: 117.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,060 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–131,712,980, 1,218 genes, copy number 7–10 (broad region; genes not listed).
- chr8:132,024,216–145,066,685, 275 genes, copy number 7 (broad region; genes not listed).
- chr11:104,942,866–104,969,366, 1 gene, copy number 7: CASP4.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 7 (broad region; genes not listed).
- chr20:13,995,369–16,053,197, 1 gene, copy number 8 (within-gene range 5–10): MACROD2.
- chr20:14,322,985–14,337,614, 1 gene, copy number 8 (within-gene range 6–8): FLRT3.
- chr20:14,522,081–14,636,524, 3 genes, copy number 7–8: AL121582.1, RNF11P2, MACROD2-IT1.
- chr20:14,884,250–14,929,528, 1 gene, copy number 8 (within-gene range 5–8): MACROD2-AS1.
- chr20:15,280,764–23,879,748, 179 genes, copy number 8–10 (broad region; genes not listed).
- chr20:30,214,765–30,403,384, 8 genes, copy number 7: CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1.
- chr20:31,465,506–32,032,180, 29 genes, copy number 7–8 (within-gene range 6–8): DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L.
- chr20:37,903,111–38,337,505, 14 genes, copy number 8: VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI.

Autosomal genes at a single copy (total copy number 1): 216. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
